CCDI case PBBNSR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/4a69e0f8-6912-4890-9a6e-7b55930152b3

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Optic nerve; Age at diagnosis: 17.4 years (6,344 days).

Biospecimens (3 samples)
- Sample 0DENBU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DENCG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DENCS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
